Gene-level copy-number profile of tumor specimen TCGA-ER-A197-06A from TCGA case TCGA-ER-A197, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.5 years (30,484 days).
Specimen TCGA-ER-A197-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.de8b50af-0a56-4622-becf-d507bfb0452c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A197-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41410619-76fc-411f-88f0-b775c6ea2935

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 141; copy number 2: 19,629; copy number 3: 17,261; copy number 4: 8,513; copy number 5: 9,464; copy number 6: 2,617; copy number 7: 591; copy number 8: 503; copy number 9: 116; copy number 10: 211; copy number 11: 56; copy number 12: 136; copy number 13: 197; copy number 14: 143; copy number 15: 63; copy number 16: 10; copy number 17: 2; copy number 18: 14; copy number 21: 14; copy number 23: 91; copy number 27: 7; copy number 33: 15; copy number 35: 1; copy number 38: 10; copy number 48: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A197-06A-32D-A191-01): tumor purity 0.31, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14,263 genes in 120 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,603 genes, copy number 5–48 (broad region; genes not listed).
- chr2:38,814–84,040,720, 1,391 genes, copy number 6 (broad region; genes not listed).
- chr2:156,011,530–159,904,756, 62 genes, copy number 6–16 (within-gene range 4–16) (broad region; genes not listed).
- chr3:197,042,560–198,222,513, 36 genes, copy number 6–12 (within-gene range 2–12): DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:40,142,198–42,391,651, 45 genes, copy number 6 (within-gene range 3–6): AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802, AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1.
- chr4:55,595,229–59,180,414, 60 genes, copy number 5–11 (within-gene range 2–11): NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1.
- chr5:58,198–40,067,200, 618 genes, copy number 5 (broad region; genes not listed).
- chr5:90,529,344–94,176,029, 41 genes, copy number 5 (within-gene range 3–5): ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, AC093298.2, PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1.
- chr5:98,576,341–100,657,970, 38 genes, copy number 5: CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1.
- chr6:1,312,098–12,297,194, 217 genes, copy number 8–17 (broad region; genes not listed).
- chr6:25,782,915–36,622,512, 665 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr6:39,299,001–44,307,506, 161 genes, copy number 6 (broad region; genes not listed).
- chr6:95,504,182–102,070,083, 60 genes, copy number 5–10 (within-gene range 4–10): CYCSP17, MANEA-DT, MANEA, AL607077.1, AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1.
- chr6:106,271,634–128,761,808, 330 genes, copy number 5–15 (broad region; genes not listed).
- chr7:13,339,201–19,117,636, 59 genes, copy number 5 (within-gene range 3–5): AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1.
- chr7:63,011,463–77,957,503, 408 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:78,939,850–139,544,985, 1,019 genes, copy number 5–9 (broad region; genes not listed).
- chr7:142,320,677–159,233,377, 430 genes, copy number 5–7 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5 (broad region; genes not listed).
- chr12:45,874,035–50,083,611, 173 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:68,332,888–70,920,738, 60 genes, copy number 7–14 (within-gene range 2–14): LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr13:18,467,172–20,773,961, 78 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:87,379,472–92,873,682, 54 genes, copy number 6 (within-gene range 4–6): LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29, AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4.
- chr14:22,011,910–22,530,378, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:29,120,254–30,772,993, 61 genes, copy number 14 (within-gene range 3–14) (broad region; genes not listed).
- chr15:68,749,501–72,602,987, 86 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr15:74,843,730–78,245,688, 112 genes, copy number 10–27 (within-gene range 2–27) (broad region; genes not listed).
- chr15:89,830,599–90,386,063, 37 genes, copy number 6 (within-gene range 2–6): AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4.
- chr17:1,003,518–2,587,866, 72 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:3,385,930–4,642,294, 53 genes, copy number 8–12: OR1R1P, OR1E1, OR3A3, OR1E2, AC025125.1, SPATA22, ASPA, TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1, NCBP3, CAMKK1, P2RX1, ATP2A3, LINC01975, ZZEF1, RNA5SP434, CYB5D2, ANKFY1, AC087292.1, Y_RNA, RYKP1, AC087742.1, UBE2G1, MFSD1P1, RN7SL774P, SPNS3, AC127521.1, AC118754.1, SPNS2, MYBBP1A, GGT6, AC118754.2, TXNP4, SMTNL2, LINC01996, RNU6-955P, ALOX15.
- chr17:4,807,152–7,219,841, 101 genes, copy number 7–33 (within-gene range 2–33) (broad region; genes not listed).
- chr17:18,537,800–19,190,245, 45 genes, copy number 8–9: CCDC144B, AC107983.1, Metazoa_SRP, TBC1D28, AC026271.2, AC026271.4, AC026271.1, ZNF286B, FOXO3B, UBE2SP2, TRIM16L, AC026271.3, FBXW10, TVP23B, AC107982.3, AC107982.1, PRPSAP2, RN7SL627P, AC107982.2, AC090286.3, AC090286.2, SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1, SNORD3B-1, SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C.
- chr18:47,390–13,125,052, 297 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:30,290,161–32,470,882, 50 genes, copy number 5 (within-gene range 4–5): AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 5 (broad region; genes not listed).
- chr20:4,852,356–7,371,692, 55 genes, copy number 5 (within-gene range 4–5): SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2, AL096799.1, LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062.
- chr20:25,919,499–64,313,132, 931 genes, copy number 5 (broad region; genes not listed).
- chr22:16,671,090–17,628,749, 47 genes, copy number 9–15: ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP, CECR3, CECR9, RN7SL843P, CECR2, FO681548.1, CLCP1, DNAJA1P6, AC007666.2, SLC25A18, AC007666.1, ATP6V1E1.
- chr22:20,017,014–23,402,726, 274 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr22:35,119,824–36,267,530, 39 genes, copy number 5 (within-gene range 3–5): LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1.

Autosomal genes at a single copy (total copy number 1): 141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
